Gene-level copy-number profile of tumor specimen TCGA-2G-AAF9-01A from TCGA case TCGA-2G-AAF9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-2G-AAF9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 784f826f-d8b0-47a7-b313-77c63957a4d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAF9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/a78a7614-5597-4678-8e08-00e268bdd20d

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 437; copy number 2: 4,217; copy number 3: 10,727; copy number 4: 11,148; copy number 5: 14,772; copy number 6: 6,208; copy number 7: 6,087; copy number 8: 1,652; copy number 9: 2,040; copy number 10: 832; copy number 11: 704; copy number 12: 48; copy number 13: 15; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,843,750–21,877,735, 3 genes: MIR3118-4, POTEB, RNU6-631P.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.
- chr15:22,178,107–22,185,402, 2 genes: IGHV1OR15-3, IGHV4OR15-8.
- chr16:32,439,069–32,460,362, 3 genes: PABPC1P13, AC138915.3, AC138915.1.
- chr16:32,600,299–32,788,944, 16 genes: AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 768 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:19,148,510–21,145,967, 16 genes, copy number 11–13 (within-gene range 4–13): KCNH8, MIR4791, AC061958.1, EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18, KAT2B, MIR3135A, SGO1, SGO1-AS1, RNU6-822P, AC116096.1.
- chr12:166,856–27,935,749, 699 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr12:31,853,021–34,249,958, 52 genes, copy number 11–12: AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr15:22,160,431–22,160,868, 1 gene, copy number 15: IGHV1OR15-1.

Autosomal genes at a single copy (total copy number 1): 437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
